Somatic mutation profile of tumor specimen TCGA-50-6593-01A (aliquot TCGA-50-6593-01A-11D-1753-08) from TCGA case TCGA-50-6593, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.7 years (18,152 days).
Specimen TCGA-50-6593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23d0de5d-9159-4edb-969e-efb3e580e56e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-6593-11A (Solid Tissue Normal), aliquot TCGA-50-6593-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/463e5386-ef24-48ae-b39c-4c13ab36e6be

The open-access MAF lists 331 somatic variants for this specimen: 248 protein-altering or splice-affecting, 75 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 75, Nonsense Mutation 17, Splice Site 8, Frame Shift Del 5, RNA 4, Splice Region 3, Frame Shift Ins 2, Intron 2, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886183, CM960375, COSV100087094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs863223740, CM158377, COSV59281245; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-1G>C p.X225_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | hotspot (GDC flag); catalogued as CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; called by muse, mutect2, varscan2
- ABCB1 | c.3764G>T p.G1255V | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55961017; called by muse, mutect2, varscan2
- ABCC9 | c.2977C>A p.L993M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV53983056; called by muse, mutect2, varscan2
- AC005833.1 | c.1316G>C p.C439S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); catalogued as COSV52900855; called by muse, mutect2, varscan2
- AC100868.1 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51849811, COSV51851501; called by muse, mutect2, varscan2
- ADAM23 | c.1789-1G>T p.X597_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100007232, COSV52227109; called by muse, mutect2, varscan2
- ADAM7 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.837); catalogued as COSV51545515; called by muse, mutect2, varscan2
- ADAMTS17 | c.1016C>G p.A339G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51491424; called by muse, mutect2, varscan2
- ADAMTS2 | c.3236A>G p.Y1079C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52389366; called by muse, mutect2, varscan2
- ADGRB1 | c.1522T>A p.W508R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1252783918, COSV100029410; called by mutect2, varscan2
- AGBL5 | c.2490-2A>T p.X830_splice | Splice Site (SNP) | VAF 15/98 reads (15%) | catalogued as COSV64080510; called by muse, mutect2, varscan2
- AHNAK2 | c.2908G>T p.A970S | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as rs749837805, COSV60927275; called by muse, mutect2, varscan2
- ALG11 | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs766585563, COSV101584262; called by muse, mutect2, varscan2
- AMIGO1 | c.1091A>G p.H364R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as COSV100880996; called by muse, mutect2, varscan2
- ARHGEF10L | c.2927C>G p.T976S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51439004; called by muse, mutect2, varscan2
- ARHGEF38 | c.392_393insTATC p.R131Sfs*7 | Frame Shift Ins (INS) | VAF 19/219 reads (9%) | catalogued as COSV99486142; called by mutect2, pindel
- ARL14 | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV100296440; called by muse, mutect2, varscan2
- ASPM | c.9660G>T p.W3220C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.349); catalogued as COSV54136740; called by muse, mutect2, varscan2
- ASPM | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 21/170 reads (12%) | catalogued as COSV54136754; called by muse, mutect2, varscan2
- ASTN2 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV57810898; called by muse, mutect2, varscan2
- ATG2B | c.5950C>G p.H1984D | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as COSV55891853; called by muse, mutect2, varscan2
- ATP13A2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV58702685; called by muse, mutect2, varscan2
- ATP1A4 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs1329382958, COSV63628141; called by muse, mutect2, varscan2
- ATXN1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs752493191, COSV55228262; called by muse, mutect2, varscan2
- BCKDHB | c.275-1G>T p.X92_splice | Splice Site (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100243371; called by muse, mutect2, varscan2
- BOD1L1 | c.8428A>T p.T2810S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV50046811; called by muse, mutect2, varscan2
- BRCA1 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100524907, COSV58797251; called by muse, mutect2, varscan2
- BTNL3 | c.93G>T p.L31F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.71); catalogued as COSV61565101; called by muse, mutect2, varscan2
- C2orf66 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.272); catalogued as rs764173375, COSV61099129; called by muse, mutect2, varscan2
- C6 | c.2767A>C p.K923Q | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV54716537; called by muse, mutect2
- CA2 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM042313, COSV53407986; called by muse, mutect2, varscan2
- CASR | c.2951G>A p.S984N (on ENST00000490131; = p.S1061N on NM_000388.4) | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56140681; called by muse, mutect2, varscan2
- CATSPERB | c.2606A>G p.Y869C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56433022; called by muse, mutect2, varscan2
- CCDC15 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 46/155 reads (30%) | catalogued as COSV100776922; called by muse, mutect2, varscan2
- CCDC158 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.219); catalogued as rs776205760, COSV66356978; called by muse, mutect2, varscan2
- CCSER2 | c.2362G>T p.G788C | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV56511025; called by muse, mutect2
- CD163L1 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as COSV100549847; called by muse, mutect2
- CDH10 | c.2197C>A p.L733I | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.699); catalogued as COSV52579000; called by muse, mutect2
- CEACAM19 | c.75G>T p.W25C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV100715411; called by muse, mutect2, varscan2
- CNTN3 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV55181858; called by muse, varscan2
- CNTN3 | c.1882G>C p.V628L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV55181868; called by muse, varscan2
- COL21A1 | c.2094G>T p.G698= | Splice Region (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99777984; called by muse, mutect2, varscan2
- COL3A1 | c.3086G>T p.G1029V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58595164; called by muse, mutect2, varscan2
- COL4A5 | c.2431G>T p.G811* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as CM072963, COSV100087090, COSV100089250, COSV60360175; called by muse, mutect2, varscan2
- CPED1 | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV60010853; called by muse, varscan2
- CRB1 | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV66332877; called by muse, mutect2, varscan2
- CRCP | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100647736, COSV58536476; called by muse, mutect2, varscan2
- CSMD3 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs769936761, COSV52143540, COSV52289632; called by muse, mutect2, varscan2
- CSRNP3 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58784471; called by muse, mutect2
- CSRNP3 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV58784477; called by muse, mutect2, varscan2
- CTTNBP2 | c.2573G>C p.S858T | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.328); catalogued as COSV50457791, COSV99352928; called by muse, mutect2, varscan2
- CUL7 | c.1113G>C p.L371F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV54812573, COSV54821030; called by muse, mutect2, varscan2
- DGKZ | c.883T>G p.S295A (on ENST00000454345 / NM_001105540.2; = p.S106A on NM_003646.4) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs533662070, COSV58993962; called by muse, mutect2, varscan2
- DICER1 | c.2761G>T p.V921F | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV58626381; called by muse, mutect2, varscan2
- DLST | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758776791, COSV53165619, COSV53167563; called by muse, mutect2, varscan2
- DLX5 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV56034025; called by muse, mutect2, varscan2
- DNAH7 | c.2684C>A p.A895D | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56780948; called by muse, mutect2, varscan2
- DNAJC3 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV65132751; called by muse, mutect2, varscan2
- DOCK11 | c.3534A>G p.I1178M | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.187); catalogued as rs1167255119, COSV52246125; called by muse, mutect2, varscan2
- DOCK2 | c.2431G>C p.D811H | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV56982006; called by muse, mutect2, varscan2
- DOCK4 | c.1547G>A p.R516K | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV70325493; called by muse, mutect2, varscan2
- DPYSL2 | c.1714G>T p.G572C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100234084, COSV60784944; called by muse, mutect2, varscan2
- DRGX | c.129G>T p.Q43H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.667); catalogued as COSV100938312; called by muse, mutect2
- EP400 | c.7729G>C p.A2577P | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57783892; called by muse, mutect2, varscan2
- FABP12 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV64617545, COSV64617590; called by muse, mutect2, varscan2
- FAM135B | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52707267, COSV52748027; called by muse, mutect2, varscan2
- FAM20B | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV55382065; called by muse, mutect2, varscan2
- FAM71B | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.077); catalogued as COSV57230384; called by muse, varscan2
- FBXO11 | c.575A>T p.D192V (on ENST00000403359 / NM_001190274.2; = p.D108V on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV57025054; called by muse, mutect2, varscan2
- FCRLA | c.303C>A p.D101E (on ENST00000367959; = p.D78E on NM_032738.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52687842; called by muse, mutect2
- FHOD3 | c.2914G>T p.G972C (on ENST00000359247 / NM_001281739.3; = p.G989C on NM_025135.5) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57185532; called by muse, mutect2, varscan2
- FLG | c.464G>T p.S155I | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV64247087; called by muse, mutect2, varscan2
- FRAS1 | c.6762A>T p.P2254= | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as COSV53639523; called by muse, mutect2
- FUBP1 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV53937037, COSV99628288; called by muse, mutect2, varscan2
- GALNT14 | c.619del p.D207Tfs*21 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as COSV100203971; called by mutect2, pindel, varscan2
- GIMAP5 | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV57529796, COSV57530350; called by muse, mutect2
- GIMAP6 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61033716, COSV61034517; called by muse, mutect2, varscan2
- GP2 | c.1105G>T p.G369W (on ENST00000381362 / NM_001007240.3; = p.G366W on NM_001502.4) | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56896108; called by muse, mutect2, varscan2
- GPR139 | c.182C>A p.S61Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100429755; called by muse, mutect2, varscan2
- GRIN2B | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV74207398; called by muse, mutect2
- GRINA | c.296A>T p.Y99F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.198); catalogued as COSV100507268; called by muse, mutect2
- HNRNPUL2 | c.1529T>A p.L510H | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV57133544; called by muse, mutect2
- HOXD10 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99982631; called by muse, mutect2, varscan2
- IBA57 | c.731A>T p.E244V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64511528; called by muse, mutect2, varscan2
- IFT88 | c.392C>T p.P131L (on ENST00000319980 / NM_001318493.2; = p.P122L on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV60676506; called by muse, mutect2, varscan2
- IGFN1 | c.2504C>A p.A835D (on ENST00000295591 / NM_001367841.1; = p.A3292D on NM_001164586.2) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.822); catalogued as COSV55182310, COSV99813356; called by muse, mutect2, varscan2
- IL36A | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV52082710, COSV52083701; called by muse, mutect2, varscan2
- ITPRID2 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1362504408, COSV57475604; called by muse, mutect2, varscan2
- KANK4 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV62988773; called by muse, mutect2, varscan2
- KCNA5 | c.548del p.G183Afs*175 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as CM102356, COSV52906752; called by mutect2, pindel
- KIAA1755 | c.1514C>A p.S505Y | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV54079785; called by muse, mutect2, varscan2
- KIF21B | c.2438G>A p.R813K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.952); catalogued as rs528414543, COSV59764345; called by muse, mutect2, varscan2
- KIF21B | c.1549C>G p.L517V | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59764355; called by muse, mutect2
- KIF2B | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV52127680; called by muse, mutect2
- KLHL20 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.253); catalogued as COSV52944511; called by muse, mutect2, varscan2
- KRT13 | c.1040A>T p.N347I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99877286; called by muse, mutect2, varscan2
- KRTAP5-5 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | PolyPhen benign (0.236); catalogued as rs559020569, COSV68785597; called by muse, mutect2, varscan2
- LAMP5 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55717742; called by muse, mutect2, varscan2
- LCE1F | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV100542680; called by muse, mutect2, varscan2
- LGALS9 | c.826G>T p.A276S (on ENST00000395473 / NM_009587.3; = p.A244S on NM_002308.4) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); catalogued as COSV56348847; called by mutect2, varscan2
- LILRB1 | c.474C>G p.Y158* (on ENST00000427581; = p.Y122* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV61121111; called by muse, mutect2
- LILRB3 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1322330653; called by muse, mutect2
- LRFN5 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1358755376, COSV53254064; called by muse, mutect2, varscan2
- LRP1 | c.10444G>A p.G3482S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV54522834; called by muse, mutect2, varscan2
- LRP1B | c.13560+1G>C p.X4520_splice | Splice Site (SNP) | VAF 13/125 reads (10%) | catalogued as COSV67197715, COSV67263369; called by muse, mutect2, varscan2
- LRP1B | c.3974C>A p.A1325D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV67189599, COSV67263374; called by muse, mutect2, varscan2
- LRP2 | c.2199G>A p.M733I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55569551; called by muse, mutect2, varscan2
- LRRIQ3 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV63043322, COSV63048837; called by muse, mutect2, varscan2
- MAGEC1 | c.2700C>A p.S900R | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV53575886, COSV53582337; called by muse, mutect2, varscan2
- MEIS2 | c.1092G>T p.Q364H (on ENST00000561208 / NM_170675.5; = p.Q344H on NM_002399.3) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54943206; called by muse, mutect2, varscan2
- MEPE | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV63074160; called by muse, mutect2, varscan2
- MFSD6 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55624710; called by muse, mutect2, varscan2
- MMP27 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV52782392; called by muse, mutect2, varscan2
- MON2 | c.4988A>G p.N1663S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.054); catalogued as COSV54813440; called by muse, mutect2, varscan2
- MUC16 | c.33598G>T p.V11200F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.222); catalogued as COSV101200789, COSV67487543; called by muse, mutect2, varscan2
- MUC16 | c.4433G>A p.S1478N | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1237602658, COSV67487544; called by muse, mutect2, varscan2
- MUC17 | c.8972G>C p.S2991T | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV60300387; called by muse, mutect2, varscan2
- MUC7 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59219874; called by muse, mutect2, varscan2
- MYO3A | c.3425A>T p.E1142V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV56345094; called by muse, mutect2
- N4BP2L2 | c.1715A>T p.K572I (on ENST00000674422; = p.K143I on NM_033111.4) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100678839; called by muse, mutect2, varscan2
- NBAS | c.5056G>T p.A1686S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV55734665; called by muse, mutect2, varscan2
- NDE1 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV61275705; called by muse, mutect2, varscan2
- NEURL1 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 55/321 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.009); catalogued as COSV100872699; called by muse, mutect2, varscan2
- NFKBID | c.775G>T p.A259S (on ENST00000396901; = p.A411S on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV61729741; called by muse, mutect2, varscan2
- NOS2 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.907); catalogued as COSV58226780; called by muse, mutect2, varscan2
- OR10A7 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100406529; called by muse, mutect2, varscan2
- OR10G9 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV66686711; called by muse, mutect2, varscan2
- OR1A2 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV101126343; called by muse, mutect2, varscan2
- OR2M7 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 101/445 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1237182900, COSV58740377; called by muse, mutect2, varscan2
- OR2M7 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV58740385; called by muse, mutect2, varscan2
- OR2T34 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs763148857, COSV100170303; called by muse, mutect2, varscan2
- OR3A3 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99351312; called by muse, mutect2, varscan2
- OR4A16 | c.841A>G p.N281D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as COSV59044236, COSV59044753, COSV59044982; called by muse, mutect2, varscan2
- OR5M8 | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59117934; called by muse, mutect2, varscan2
- OR6C70 | c.315G>T p.L105F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.046); catalogued as rs753397817, COSV59245326; called by muse, mutect2, varscan2
- OR8H1 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100476936; called by muse, mutect2, varscan2
- OTOF | c.5728G>T p.E1910* (on ENST00000272371 / NM_194248.3; = p.E1143* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV55515836; called by muse, mutect2
- PARD3B | c.3164A>T p.E1055V (on ENST00000406610 / NM_001302769.2; = p.E986V on NM_057177.7) | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV62526834; called by muse, mutect2, varscan2
- PARN | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs1215008274, COSV58369991; called by muse, mutect2, varscan2
- PCDH17 | c.2637T>A p.F879L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV64978082; called by muse, mutect2, varscan2
- PCDH7 | c.2588A>T p.Q863L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV62342644; called by muse, mutect2, varscan2
- PCDHA7 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV65339777; called by muse, mutect2, varscan2
- PCDHB1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as rs782180561, COSV60629346, COSV60629723; called by muse, mutect2, varscan2
- PCDHB13 | c.1202A>G p.Y401C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1554287867, COSV53400151; called by muse, mutect2, varscan2
- PCDHB3 | c.1921G>A p.V641M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV50616653; called by muse, mutect2, varscan2
- PDE4DIP | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV57709743, COSV57722981; called by muse, mutect2, varscan2
- PEG3 | c.2185A>G p.T729A | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.365); catalogued as COSV55644360; called by muse, mutect2, varscan2
- PIP5K1B | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55247823, COSV55256034; called by muse, mutect2, varscan2
- PJA2 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.729); catalogued as COSV63274272; called by muse, mutect2, varscan2
- PLCH1 | c.4026G>T p.E1342D (on ENST00000340059 / NM_001130960.2; = p.E1334D on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV58208249; called by muse, mutect2
- PLCH2 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV53948338; called by muse, mutect2, varscan2
- PNPT1 | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53179525; called by muse, mutect2
- PPARGC1A | c.1944A>C p.E648D | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as COSV53532529; called by muse, mutect2
- PRAMEF2 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 97/356 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99535024; called by muse, mutect2, varscan2
- PROM2 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.25); catalogued as COSV58299108, COSV58300252; called by muse, mutect2, varscan2
- PTPN9 | c.270G>C p.E90D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60725550; called by muse, mutect2, varscan2
- PTPRD | c.3895T>A p.S1299T | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV61974865; called by muse, mutect2, varscan2
- RALA | c.400A>G p.K134E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755490850, COSV50050146; called by muse, mutect2, varscan2
- RBM24 | c.442C>A p.P148T (on ENST00000379052 / NM_001143942.2; = p.P103T on NM_153020.2) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV59003135; called by muse, mutect2, varscan2
- RHBG | c.1256T>G p.F419C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54809200; called by muse, mutect2, varscan2
- RHOU | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64208990; called by muse, mutect2, varscan2
- RIC1 | c.3773A>C p.H1258P | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs777161001, COSV52614210; called by muse, mutect2, varscan2
- RICTOR | c.4037C>G p.S1346C | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57128881; called by muse, mutect2
- RIMS2 | c.960C>G p.Y320* (on ENST00000666250 / NM_001348490.2; = p.Y128* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV51715692; called by muse, mutect2, varscan2
- RIN3 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.936); catalogued as COSV53654243; called by muse, mutect2, varscan2
- RNF133 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as rs1403114177, COSV57381261; called by muse, mutect2, varscan2
- ROBO4 | c.1640G>T p.R547L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100127407, COSV60624759; called by muse, mutect2, varscan2
- RYR2 | c.7515A>G p.A2505= | Splice Region (SNP) | VAF 12/128 reads (9%) | catalogued as COSV63707782; called by muse, mutect2
- RYR2 | c.11260A>T p.M3754L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV63707792; called by muse, mutect2, varscan2
- SCN2A | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51852840; called by muse, mutect2, varscan2
- SETDB2 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as COSV51646286; called by muse, mutect2
- SEZ6L | c.2551C>A p.R851S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV50680114; called by muse, mutect2, varscan2
- SI | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV52296345; called by muse, mutect2, varscan2
- SIGLEC6 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1420960508, COSV58436828; called by muse, mutect2, varscan2
- SIRPB1 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 43/156 reads (28%) | catalogued as COSV53540468; called by muse, mutect2, varscan2
- SLC2A14 | c.1401G>T p.L467F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100533684; called by muse, varscan2
- SLITRK1 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs773468859, COSV65677171; called by muse, mutect2, varscan2
- SMS | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.187); catalogued as COSV65115035; called by muse, mutect2, varscan2
- SNX18 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.991); catalogued as rs760469131, COSV57991647; called by muse, mutect2, varscan2
- SRGAP3 | c.2744C>T p.A915V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs776049201, COSV64538342; called by muse, mutect2
- SRPX | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100655982; called by muse, mutect2, varscan2
- ST14 | c.876-1G>T p.X292_splice | Splice Site (SNP) | VAF 12/117 reads (10%) | catalogued as rs749030741, COSV53836366; called by muse, mutect2, varscan2
- STK26 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53748235; called by muse, mutect2, varscan2
- SUPT5H | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV63241686; called by muse, mutect2, varscan2
- SYTL5 | c.1973T>C p.L658P | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52904724; called by muse, varscan2
- TAF1L | c.242C>A p.T81K | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as rs764175922, COSV54267502, COSV99644025; called by muse, mutect2, varscan2
- TATDN3 | c.267T>A p.D89E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65325758; called by muse, mutect2, varscan2
- TBC1D16 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV60480692; called by muse, mutect2
- TBX20 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.921); catalogued as rs768119874, COSV68785389; called by muse, mutect2, varscan2
- TBX22 | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV64787515; called by muse, mutect2, varscan2
- TDG | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904110; called by muse, mutect2
- TDRD9 | c.2608G>T p.V870L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV59153832; called by muse, mutect2, varscan2
- TEAD1 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV57569962; called by muse, mutect2, varscan2
- TEX15 | c.8057T>A p.V2686E (on ENST00000256246; = p.V3069E on NM_001350162.2) | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as COSV56352213; called by muse, mutect2, varscan2
- THSD7A | c.3830C>A p.T1277K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.82); PolyPhen benign (0.051); catalogued as COSV69855491; called by muse, mutect2, varscan2
- THSD7B | c.2626G>T p.A876S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as COSV55728186; called by muse, mutect2, varscan2
- TIAM1 | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99733853; called by mutect2, varscan2
- TMEM132B | c.2751C>G p.I917M | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54766376; called by muse, mutect2, varscan2
- TMEM217 | c.503G>C p.R168P | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV100362502, COSV60825066; called by muse, mutect2, varscan2
- TMPRSS11F | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as COSV62468775; called by muse, mutect2, varscan2
- TNFRSF11B | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV52073571; called by muse, mutect2, varscan2
- TNR | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54908133, COSV99689444; called by muse, mutect2, varscan2
- TRIM39 | c.1476G>T p.W492C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100935673; called by muse, mutect2, varscan2
- TRPA1 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51571721; called by muse, mutect2, varscan2
- TRPC7 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61462485; called by muse, mutect2, varscan2
- TRPM6 | c.914A>C p.E305A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV62520427; called by muse, mutect2
- TSKS | c.1478G>T p.R493M | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55878482; called by muse, mutect2
- TXLNB | c.482A>T p.K161M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100624772, COSV64445342; called by muse, mutect2, varscan2
- UGT2B28 | c.1311-1G>C p.X437_splice | Splice Site (SNP) | VAF 16/93 reads (17%) | catalogued as rs1285207670, COSV59433967; called by muse, mutect2, varscan2
- UNC13C | c.6116C>A p.S2039Y | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.272); catalogued as COSV52914180; called by muse, mutect2, varscan2
- UNC79 | c.7414C>G p.L2472V (on ENST00000393151 / NM_001346218.2; = p.L2295V on NM_020818.5) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV56385231, COSV56405907; called by muse, mutect2, varscan2
- UPP1 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57978374; called by muse, mutect2, varscan2
- USP53 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 15/169 reads (9%) | catalogued as COSV99917590; called by muse, mutect2
- VAX1 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53328271, COSV53330523; called by muse, mutect2, varscan2
- VCL | c.3092G>T p.R1031L (on ENST00000211998 / NM_014000.3; = p.R963L on NM_003373.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV53013644; called by muse, mutect2, varscan2
- VIRMA | c.2414A>T p.N805I | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV52589873; called by muse, mutect2, varscan2
- VPS13A | c.2520G>C p.E840D | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100652397; called by muse, mutect2
- VPS13A | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as COSV100652400; called by muse, mutect2
- VPS45 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.668); catalogued as COSV64888855; called by muse, mutect2, varscan2
- WDFY3 | c.6500G>T p.R2167L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs746407972, COSV55711753; called by muse, mutect2, varscan2
- WDR17 | c.1462T>A p.W488R | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54581569; called by muse, mutect2, varscan2
- WNK4 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53821858; called by muse, mutect2, varscan2
- WNT8B | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59326573; called by muse, mutect2
- XDH | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV65150807; called by muse, mutect2, varscan2
- YTHDC1 | c.1096G>T p.E366* (on ENST00000344157 / NM_001031732.4; = p.E348* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV60011760; called by muse, mutect2, varscan2
- ZBED1 | c.1885G>T p.V629F | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs776217070, COSV100585369; called by muse, mutect2, varscan2
- ZBED1 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs1326015209, COSV58138115; called by muse, mutect2, varscan2
- ZC3H3 | c.1249G>T p.G417W | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV52794099; called by muse, mutect2
- ZC3H3 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV52794110; called by muse, mutect2, varscan2
- ZNF107 | c.622A>T p.I208L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61331268; called by muse, mutect2, varscan2
- ZNF304 | c.1121G>C p.R374P | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs748940178, COSV56586022; called by muse, mutect2, varscan2
- ZNF318 | c.4234G>A p.G1412R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58933316; called by muse, mutect2, varscan2
- ZNF492 | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1296443351, COSV71762322; called by muse, mutect2, varscan2
- ZNF662 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV60242815; called by muse, mutect2, varscan2
- ZNF705A | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV63733650; called by muse, mutect2, varscan2
- ZNF721 | c.811G>T p.G271C (on ENST00000338977; = p.G283C on NM_133474.4) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1421318513, COSV100167231; called by muse, mutect2
- ZWINT | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59186209; called by muse, mutect2, varscan2
- FCGBP | c.6715G>T p.G2239C | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLI2 | c.3064G>T p.A1022S (on ENST00000361492 / NM_001374353.1; = p.A1039S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.583); called by muse, mutect2
- IGLV4-3 | c.154A>T p.I52F | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- KNSTRN | c.485+2dup p.X162_splice | Splice Site (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- NF1 | c.3802del p.A1268Qfs*17 | Frame Shift Del (DEL) | VAF 73/384 reads (19%) | called by mutect2, pindel, varscan2
- NF1 | c.7614del p.G2539Efs*9 (on ENST00000358273 / NM_001042492.3; = p.G2518Efs*9 on NM_000267.3) | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- PKLR | c.1510del p.R504Afs*26 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.2808_2809insT p.Q937Sfs*16 | Frame Shift Ins (INS) | VAF 23/115 reads (20%) | called by mutect2, pindel*, varscan2
- TRAV26-1 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- ACSM5 | c.318G>C p.L106= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV59374153; called by muse, mutect2, varscan2
- AOPEP | c.2196C>A p.L732= (on ENST00000375315 / NM_001193329.1; = p.L633= on NM_032823.5) | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV52997430; called by muse, mutect2, varscan2
- ASAH1 | c.54C>G p.S18= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100025608; called by muse, mutect2
- ASXL3 | c.4149C>T p.A1383= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV52476550; called by muse, mutect2, varscan2
- ATP10B | c.1275C>A p.G425= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV58780816; called by muse, mutect2, varscan2
- ATP2B2 | c.408G>C p.T136= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV59505678; called by muse, mutect2, varscan2
- ATP6V1C2 | c.870G>A p.P290= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs771976464, COSV55364155; called by muse, mutect2, varscan2
- BSND | c.390C>T p.S130= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV64871297; called by muse, mutect2
- CCM2 | c.345G>C p.L115= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51850493, COSV51850792; called by muse, mutect2, varscan2
- CD84 | c.51G>T p.P17= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100245898; called by muse, mutect2
- CDK15 | c.69C>A p.G23= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs769401397, COSV99642883; called by muse, mutect2, varscan2
- CNNM1 | c.1335C>T p.D445= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100763797; called by muse, mutect2, varscan2
- COL6A1 | c.2622G>T p.A874= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV62613249, COSV62615143; called by muse, mutect2, varscan2
- CPZ | c.1437C>T p.P479= (on ENST00000360986 / NM_001014447.3; = p.P468= on NM_003652.3) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV59925289; called by muse, mutect2, varscan2
- CSMD3 | c.237T>A p.P79= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as COSV52289611; called by muse, mutect2
- CTCFL | c.216G>C p.S72= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV54777063, COSV54778121; called by muse, mutect2, varscan2
- CTTNBP2 | c.1056C>A p.A352= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV50458044; called by muse, mutect2
- CUBN | c.8337G>T p.L2779= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100912314; called by muse, mutect2, varscan2
- DACT1 | c.1269A>G p.S423= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs965230880, COSV60022961; called by muse, mutect2
- DNAJC5B | c.76C>T p.L26= | Silent (SNP) | VAF 17/196 reads (9%) | catalogued as COSV99395516; called by muse, mutect2
- DOCK2 | c.3282G>A p.E1094= | Silent (SNP) | VAF 36/254 reads (14%) | catalogued as COSV56982017; called by muse, mutect2, varscan2
- DST | c.6697T>C p.L2233= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs537976334, COSV99753115; called by muse, mutect2, varscan2
- DYSF | c.4285C>T p.L1429= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV50302192; called by muse, mutect2, varscan2
- ENG | c.1056G>C p.P352= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100785187, COSV61228579; called by muse, mutect2, varscan2
- EP400 | c.3678G>T p.V1226= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1437218886, COSV57783873; called by muse, mutect2, varscan2
- EYA2 | c.600C>A p.S200= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV57949508; called by muse, mutect2, varscan2
- FAM135B | c.753T>A p.A251= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV52748044; called by muse, mutect2
- FER1L6 | c.2506C>A p.R836= | Silent (SNP) | VAF 26/121 reads (21%) | catalogued as COSV67552271; called by muse, mutect2, varscan2
- FHOD3 | c.3801G>T p.R1267= (on ENST00000359247 / NM_001281739.3; = p.R1284= on NM_025135.5) | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99940646; called by muse, mutect2, varscan2
- GINS2 | c.396T>C p.A132= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV53675294; called by muse, mutect2, varscan2
- GPR139 | c.183C>A p.S61= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100429753; called by muse, mutect2, varscan2
- GRM1 | c.832C>A p.R278= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV51132803, COSV51271244; called by muse, mutect2, varscan2
- HPGD | c.207A>G p.Q69= | Silent (SNP) | VAF 22/211 reads (10%) | catalogued as rs146392763; called by muse, mutect2, varscan2
- ICE1 | c.6582G>T p.S2194= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV56830736, COSV99665685; called by muse, mutect2, varscan2
- IL7R | c.732C>A p.T244= | Silent (SNP) | VAF 13/380 reads (3%) | catalogued as COSV57412227, COSV57413715; called by muse, mutect2
- INTU | c.840G>A p.Q280= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV56541684; called by muse, mutect2, varscan2
- KCNT2 | c.3090T>G p.G1030= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV54103217; called by muse, mutect2, varscan2
- KRT14 | c.948G>A p.E316= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV51422825; called by muse, mutect2, varscan2
- LRRC18 | c.699A>G p.R233= | Silent (SNP) | VAF 27/230 reads (12%) | catalogued as rs751747848, COSV53285497; called by muse, mutect2, varscan2
- LRRC8A | c.762G>T p.V254= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV52188681; called by muse, mutect2, varscan2
- LRRC8E | c.2202G>A p.L734= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV60719029; called by muse, mutect2, varscan2
- MED23 | c.453A>T p.T151= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV63436399; called by muse, mutect2, varscan2
- MMP16 | c.216C>A p.A72= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV54184446; called by muse, mutect2, varscan2
- MTA3 | c.552A>T p.P184= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV68136312; called by muse, mutect2, varscan2
- MYRF | c.1167G>T p.V389= (on ENST00000278836 / NM_001127392.3; = p.V380= on NM_013279.4) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53892923; called by muse, mutect2, varscan2
- NID2 | c.1584A>T p.A528= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV53501578; called by muse, mutect2, varscan2
- OR2A1 | c.342G>A p.L114= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV101283369; called by muse, varscan2
- OR3A3 | c.876C>A p.P292= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV99351317; called by muse, mutect2, varscan2
- OR4D6 | c.615G>T p.L205= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV55660787; called by muse, mutect2, varscan2
- OSBPL5 | c.1584G>A p.E528= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV55144931; called by mutect2, varscan2
- PADI4 | c.561G>A p.T187= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs775568062, COSV64924876; called by muse, mutect2, varscan2
- PAPPA2 | c.5043T>C p.C1681= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100867720; called by muse, varscan2
- PCDHA12 | c.1356G>T p.A452= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV56501088, COSV56537959; called by muse, mutect2, varscan2
- POC1B | c.942C>G p.L314= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV57968007; called by muse, mutect2, varscan2
- RUNX1T1 | c.1053A>C p.A351= (on ENST00000265814 / NM_001198628.1; = p.A324= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/309 reads (6%) | catalogued as COSV56160273, COSV99750296; called by muse, mutect2
- RYR3 | c.3723C>T p.L1241= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1263214293, COSV66796688, COSV66805355; called by muse, mutect2, varscan2
- SLAIN2 | c.720A>G p.S240= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV51909832; called by muse, mutect2
- SLC12A3 | c.1366C>T p.L456= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV52638248; called by muse, mutect2, varscan2
- SLCO1B3 | c.1444C>T p.L482= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as rs377513667; called by muse, mutect2, varscan2
- SPATA31D1 | c.1017T>C p.S339= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs1302945005, COSV61194770; called by muse, mutect2, varscan2
- SUSD4 | c.216A>G p.G72= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV59555830; called by muse, mutect2, varscan2
- TDRD6 | c.4875G>C p.L1625= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV60177988; called by muse, mutect2, varscan2
- TMIGD1 | c.291C>T p.N97= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs199924056, COSV61029219; called by muse, mutect2, varscan2
- TTLL8 | c.483A>T p.T161= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99838150; called by muse, mutect2, varscan2
- TTN | c.59913T>G p.A19971= (on ENST00000591111; = p.A12547= on NM_003319.4) | Silent (SNP) | VAF 31/281 reads (11%) | catalogued as COSV60284100; called by muse, mutect2, varscan2
- UNC45B | c.2442G>T p.G814= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs760747004, COSV99268397; called by muse, mutect2, varscan2
- UNC79 | c.3036G>A p.L1012= (on ENST00000393151 / NM_001346218.2; = p.L835= on NM_020818.5) | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV56405890; called by muse, mutect2, varscan2
- UQCRC1 | c.195T>C p.S65= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99178947; called by muse, mutect2, varscan2
- USP53 | c.363G>C p.A121= | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- VPS13A | c.3495A>G p.L1165= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs977841147, COSV62437081; called by muse, mutect2, varscan2
- XCL1 | c.120G>A p.L40= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs1474534974, COSV63192760; called by muse, mutect2, varscan2
- XCL2 | c.120G>A p.L40= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1171668985, COSV63194765; called by muse, mutect2
- ZBED1 | c.1884G>T p.V628= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as COSV100585372; called by muse, mutect2, varscan2
- ZDHHC9 | c.141G>T p.G47= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV64097287; called by muse, mutect2, varscan2
- ZNF439 | c.678C>T p.L226= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV58310806; called by muse, mutect2, varscan2
- AC244258.1 | n.318C>T | RNA (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506184 C>T | 3'Flank (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- DCHS2 | n.8538G>T | RNA (SNP) | VAF 19/216 reads (9%) | catalogued as COSV61778175; called by muse, mutect2
- DCHS2 | n.8536T>C | RNA (SNP) | VAF 20/224 reads (9%) | catalogued as COSV61778179; called by muse, mutect2
- NEUROG1 | c.-1G>A | 5'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as rs1194896653; called by muse, mutect2, varscan2
- PDGFD | c.125-36657G>T | Intron (SNP) | VAF 40/144 reads (28%) | catalogued as COSV56390937; called by muse, mutect2, varscan2
- RPS26P15 | n.52G>C | RNA (SNP) | VAF 6/65 reads (9%) | catalogued as rs746411167; called by muse, mutect2, varscan2
- SLC2A8 | c.426+203A>T | Intron (SNP) | VAF 8/48 reads (17%) | called by muse, varscan2
